Somatic mutation profile of tumor specimen C3N-01411-04 (aliquot CPT0105420009) from CPTAC case C3N-01411, project CPTAC-3 (Bronchus and lung — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G3; Age at diagnosis: 64.2 years (23,433 days).
Specimen C3N-01411-04: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 47566312-1637-4bd9-afd7-f98b50df8a6f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-01411-31 (Blood Derived Normal), aliquot CPT0107860002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/216a4004-88c1-4be1-ac47-703ed29ee18b

The open-access MAF lists 527 somatic variants for this specimen: 356 protein-altering or splice-affecting, 97 silent, 74 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 315, Silent 97, Intron 33, Nonsense Mutation 17, RNA 17, Splice Site 12, 3'UTR 8, 5'Flank 8, 5'UTR 6, Frame Shift Del 5, Splice Region 3, Frame Shift Ins 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DCX | c.192C>G p.Y64* | Nonsense Mutation (SNP) | VAF 97/313 reads (31%) | catalogued as rs764964209; ClinVar: pathogenic; called by muse, mutect2, varscan2
- HRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 128/334 reads (38%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.339); catalogued as rs104894230, CM053284, CM081305, CM123157, COSV54236734, COSV54236774, COSV54238174; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.1015G>T p.E339* | Nonsense Mutation (SNP) | VAF 125/247 reads (51%) | catalogued as rs17882252, CM984588, COSV52705645, COSV52980241, COSV53040770, COSV53664260; ClinVar: pathogenic; called by muse, mutect2, varscan2
- A4GALT | c.14C>T p.P5L | Missense Mutation (SNP) | VAF 31/279 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as rs1291430666; called by muse, mutect2, varscan2
- ACTBL2 | c.212C>A p.P71H | Missense Mutation (SNP) | VAF 177/306 reads (58%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs1447698445; called by muse, mutect2, varscan2
- ADCY2 | c.773C>T p.A258V | Missense Mutation (SNP) | VAF 34/132 reads (26%) | SIFT tolerated (0.18); PolyPhen benign (0.222); catalogued as rs1391205277, COSV57887882, COSV57892610; called by muse, mutect2, varscan2
- ADCY8 | c.814G>A p.G272S | Missense Mutation (SNP) | VAF 131/460 reads (28%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as COSV53921081; called by muse, mutect2, varscan2
- AGPS | c.1723G>C p.A575P | Missense Mutation (SNP) | VAF 201/608 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV51564456; called by muse, mutect2, varscan2
- AHNAK | c.7435G>C p.E2479Q | Missense Mutation (SNP) | VAF 7/125 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV57211919; called by muse, mutect2
- ANGPT4 | c.456G>T p.M152I | Missense Mutation (SNP) | VAF 56/173 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV67922821; called by muse, mutect2, varscan2
- AP3B2 | c.1466C>A p.A489E | Missense Mutation (SNP) | VAF 125/203 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1474316601; called by muse, mutect2, varscan2
- AP3B2 | c.1465G>A p.A489T | Missense Mutation (SNP) | VAF 127/201 reads (63%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.784); catalogued as rs1264307794; called by muse, mutect2, varscan2
- AR | c.2659A>T p.M887L | Missense Mutation (SNP) | VAF 197/274 reads (72%) | SIFT tolerated (0.27); PolyPhen benign (0.007); catalogued as rs755226547, CM990170, COSV65964956; called by muse, mutect2, varscan2
- ATG10 | c.483T>G p.F161L | Missense Mutation (SNP) | VAF 145/266 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56422750; called by muse, mutect2, varscan2
- ATP8B3 | c.2665C>A p.R889S | Missense Mutation (SNP) | VAF 139/176 reads (79%) | SIFT tolerated (0.22); PolyPhen benign (0.109); catalogued as rs935509808, COSV59547863; called by muse, mutect2, varscan2
- ATP8B4 | c.529C>A p.H177N | Missense Mutation (SNP) | VAF 60/99 reads (61%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs1163570810; called by muse, mutect2, varscan2
- CBY2 | c.550G>A p.E184K | Missense Mutation (SNP) | VAF 31/694 reads (4%) | SIFT tolerated (0.64); PolyPhen benign (0.176); catalogued as rs555632513; called by muse, mutect2
- CCDC180 | c.3753G>T p.E1251D | Missense Mutation (SNP) | VAF 107/414 reads (26%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as COSV63831925; called by muse, mutect2, varscan2
- CHD1L | c.290C>T p.P97L | Missense Mutation (SNP) | VAF 18/160 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.444); catalogued as COSV100787575; called by muse, mutect2, varscan2
- CRYBG3 | c.5864G>T p.G1955V | Missense Mutation (SNP) | VAF 15/90 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.014); catalogued as COSV51712658; called by muse, mutect2, varscan2
- CSMD3 | c.6991G>T p.E2331* (on ENST00000297405 / NM_001363185.1; = p.E2227* on NM_052900.3) | Nonsense Mutation (SNP) | VAF 89/419 reads (21%) | catalogued as COSV52109234, COSV52230881; called by muse, mutect2, varscan2
- CYP39A1 | c.270dup p.V91Sfs*4 | Frame Shift Ins (INS) | VAF 124/276 reads (45%) | catalogued as rs1225765844; called by mutect2, pindel, varscan2
- CYP4F12 | c.490A>G p.I164V | Missense Mutation (SNP) | VAF 176/514 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs372624515; called by muse, mutect2, varscan2
- DAB2 | c.1639G>A p.G547S | Missense Mutation (SNP) | VAF 354/669 reads (53%) | SIFT tolerated (0.28); PolyPhen benign (0.043); catalogued as COSV57913604; called by muse, mutect2, varscan2
- DNAH5 | c.11654G>T p.R3885L | Missense Mutation (SNP) | VAF 107/269 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV99453747; called by muse, mutect2, varscan2
- DUOX1 | c.490G>A p.D164N | Missense Mutation (SNP) | VAF 7/119 reads (6%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.497); catalogued as COSV100368434; called by muse, mutect2
- EPDR1 | c.460A>G p.R154G | Missense Mutation (SNP) | VAF 80/241 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs768112913; called by muse, mutect2, varscan2
- EYS | c.5054C>T p.S1685L | Missense Mutation (SNP) | VAF 64/206 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.122); catalogued as COSV58201867; called by muse, mutect2, varscan2
- FAM135B | c.1708G>T p.V570L | Missense Mutation (SNP) | VAF 87/200 reads (44%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs768314952; called by muse, mutect2, varscan2
- FAM166B | c.208_210del p.P70del | In Frame Del (DEL) | VAF 202/546 reads (37%) | catalogued as rs1199997622; called by mutect2, pindel, varscan2
- FASTKD2 | c.1870G>T p.D624Y | Missense Mutation (SNP) | VAF 121/381 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.87); catalogued as rs1204974208, COSV52700242; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FAT3 | c.437T>C p.I146T | Missense Mutation (SNP) | VAF 85/181 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.544); catalogued as rs1398809924, COSV99963144; called by muse, mutect2, varscan2
- FBN1 | c.1031G>T p.R344L | Missense Mutation (SNP) | VAF 168/300 reads (56%) | SIFT deleterious (0.01); PolyPhen benign (0.38); catalogued as rs200388305; called by muse, mutect2, varscan2
- FLG | c.6227C>T p.A2076V | Missense Mutation (SNP) | VAF 136/1245 reads (11%) | SIFT tolerated (0.36); PolyPhen benign (0.011); catalogued as rs1465602012; called by muse, mutect2, varscan2
- FNIP1 | c.3221G>A p.G1074E | Missense Mutation (SNP) | VAF 125/223 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1286838387; called by muse, mutect2, varscan2
- G6PD | c.829G>T p.A277S | Missense Mutation (SNP) | VAF 84/133 reads (63%) | SIFT tolerated (0.08); PolyPhen benign (0.099); catalogued as COSV63702853; called by muse, mutect2, varscan2
- GJD2 | c.589C>T p.R197C | Missense Mutation (SNP) | VAF 137/231 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV51747974; called by muse, mutect2, varscan2
- HAND2 | c.567G>C p.L189F | Missense Mutation (SNP) | VAF 16/330 reads (5%) | SIFT tolerated (0.33); PolyPhen benign (0.009); catalogued as COSV100854265, COSV64018546; called by muse, mutect2
- HDAC9 | c.2577G>T p.E859D | Missense Mutation (SNP) | VAF 102/336 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV67781673; called by muse, mutect2, varscan2
- HGF | c.646G>C p.G216R | Missense Mutation (SNP) | VAF 191/560 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV55950541, COSV99738608; called by muse, mutect2, varscan2
- HIVEP1 | c.2866G>C p.G956R | Missense Mutation (SNP) | VAF 124/337 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65102423; called by muse, varscan2
- HSPG2 | c.2665G>A p.G889R | Missense Mutation (SNP) | VAF 16/185 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs375748367; called by muse, mutect2
- INO80B | c.971G>T p.R324L | Missense Mutation (SNP) | VAF 80/209 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.634); catalogued as COSV51968856, COSV51971200; called by muse, mutect2, varscan2
- ITPRID2 | c.163G>A p.E55K | Missense Mutation (SNP) | VAF 12/270 reads (4%) | SIFT tolerated (0.37); PolyPhen benign (0.04); catalogued as rs1419126235, COSV57470244; called by muse, mutect2
- JMJD1C | c.1975A>G p.K659E | Missense Mutation (SNP) | VAF 101/168 reads (60%) | SIFT tolerated (0.06); PolyPhen benign (0.272); catalogued as rs750493771; called by muse, mutect2, varscan2
- KANK3 | c.232C>T p.P78S | Missense Mutation (SNP) | VAF 20/20 reads (100%) | SIFT tolerated (0.98); PolyPhen benign (0.001); catalogued as rs994788562; called by muse, mutect2
- KCNH5 | c.1454T>G p.L485R | Missense Mutation (SNP) | VAF 189/484 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV59768171; called by muse, mutect2, varscan2
- KCNT1 | c.638G>A p.R213Q (on ENST00000488444; = p.R232Q on NM_020822.3) | Missense Mutation (SNP) | VAF 152/445 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.145); catalogued as COSV53696046; called by muse, mutect2, varscan2
- KIFAP3 | c.670A>G p.M224V | Missense Mutation (SNP) | VAF 72/341 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs1261574912; called by muse, mutect2, varscan2
- KIR2DL1 | c.406G>T p.G136C | Missense Mutation (SNP) | VAF 87/169 reads (51%) | SIFT deleterious (0.02); PolyPhen benign (0.42); catalogued as rs755160637, COSV99382710; called by muse, varscan2
- KNDC1 | c.2693G>T p.R898L | Missense Mutation (SNP) | VAF 76/175 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.172); catalogued as COSV100465949; called by muse, mutect2, varscan2
- LCE1D | c.163G>A p.G55S | Missense Mutation (SNP) | VAF 276/511 reads (54%) | PolyPhen benign (0.089); catalogued as rs776581978, COSV100405901; called by muse, mutect2, varscan2
- LRRC4C | c.1647G>T p.K549N | Missense Mutation (SNP) | VAF 130/347 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53425185; called by muse, mutect2, varscan2
- LRRC9 | c.338T>C p.I113T | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1265838328; called by muse, mutect2, varscan2
- MDFI | c.523G>C p.E175Q | Missense Mutation (SNP) | VAF 117/176 reads (66%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.829); catalogued as COSV57822983; called by muse, mutect2, varscan2
- MMP16 | c.1217T>G p.F406C | Missense Mutation (SNP) | VAF 24/155 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99687404; called by muse, mutect2, varscan2
- MOB3A | c.145G>A p.V49M | Missense Mutation (SNP) | VAF 250/315 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs145491125, COSV63865985; called by muse, mutect2, varscan2
- MOSPD1 | c.286C>T p.R96C | Missense Mutation (SNP) | VAF 36/158 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs1346149906; called by muse, mutect2, varscan2
- MPP7 | c.407C>T p.S136L | Missense Mutation (SNP) | VAF 104/303 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1169513038; called by muse, mutect2, varscan2
- MST1L | n.66C>A | Splice Region (SNP) | VAF 49/430 reads (11%) | catalogued as rs1364781923; called by muse, varscan2
- MYBBP1A | c.680C>T p.S227F | Missense Mutation (SNP) | VAF 86/143 reads (60%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.49); catalogued as rs192014005; called by muse, mutect2, varscan2
- MYNN | c.1639A>T p.S547C | Missense Mutation (SNP) | VAF 90/254 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.971); catalogued as COSV62991062; called by muse, mutect2, varscan2
- NELL2 | c.185-1G>T p.X62_splice | Splice Site (SNP) | VAF 95/129 reads (74%) | catalogued as rs76394845; called by muse, mutect2
- NLRP13 | c.862G>T p.D288Y | Missense Mutation (SNP) | VAF 90/157 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV61624387; called by muse, mutect2, varscan2
- NLRP14 | c.631A>T p.K211* | Nonsense Mutation (SNP) | VAF 165/418 reads (39%) | catalogued as COSV100205490; called by muse, mutect2, varscan2
- NOP2 | c.923G>A p.R308Q (on ENST00000322166 / NM_001258308.2; = p.R304Q on NM_006170.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 91/271 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs762870503; called by muse, mutect2, varscan2
- NRROS | c.734G>A p.G245E | Missense Mutation (SNP) | VAF 106/341 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs748408648; called by muse, mutect2, varscan2
- NTAN1 | c.451G>A p.E151K | Missense Mutation (SNP) | VAF 15/265 reads (6%) | SIFT tolerated (0.97); PolyPhen benign (0.003); catalogued as rs945988067; called by muse, mutect2
- NUP153 | c.3974C>T p.P1325L | Missense Mutation (SNP) | VAF 11/212 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV100020505; called by muse, mutect2
- OGDHL | c.617del p.G206Afs*25 | Frame Shift Del (DEL) | VAF 79/172 reads (46%) | catalogued as COSV65104886; called by mutect2, pindel, varscan2
- OR1A1 | c.655C>G p.R219G | Missense Mutation (SNP) | VAF 31/198 reads (16%) | SIFT tolerated (0.28); PolyPhen benign (0.268); catalogued as COSV58403287; called by muse, mutect2, varscan2
- OR2T8 | c.889G>A p.G297R | Missense Mutation (SNP) | VAF 64/399 reads (16%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.816); catalogued as rs1208698913, COSV60661569; called by muse, mutect2, varscan2
- OR2W3 | c.238C>G p.Q80E | Missense Mutation (SNP) | VAF 72/515 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100831736; called by muse, mutect2, varscan2
- OR4K14 | c.417G>A p.W139* | Nonsense Mutation (SNP) | VAF 78/215 reads (36%) | catalogued as rs867798282, COSV59292112; called by muse, mutect2, varscan2
- OR52R1 | c.647T>C p.V216A | Missense Mutation (SNP) | VAF 145/491 reads (30%) | SIFT tolerated (0.31); PolyPhen benign (0.014); catalogued as rs997897309; called by muse, mutect2, varscan2
- OR5D13 | c.422A>C p.K141T | Missense Mutation (SNP) | VAF 24/200 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.364); catalogued as rs1275361934; called by muse, mutect2, varscan2
- OR8H1 | c.616C>A p.L206M | Missense Mutation (SNP) | VAF 123/204 reads (60%) | SIFT tolerated (0.25); PolyPhen benign (0.213); catalogued as COSV57293370; called by muse, mutect2, varscan2
- ORC4 | c.373G>C p.G125R | Missense Mutation (SNP) | VAF 106/306 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.904); catalogued as COSV51575220; called by muse, mutect2, varscan2
- PELI2 | c.460C>G p.R154G | Missense Mutation (SNP) | VAF 189/587 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV50709950; called by muse, mutect2, varscan2
- PLEKHA7 | c.2807C>T p.P936L | Missense Mutation (SNP) | VAF 80/220 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1201549110; called by muse, mutect2, varscan2
- POTEG | c.309C>A p.C103* | Nonsense Mutation (SNP) | VAF 168/1666 reads (10%) | catalogued as COSV73631105; called by muse, mutect2, varscan2
- PPP1R3A | c.1390G>A p.G464R | Missense Mutation (SNP) | VAF 95/242 reads (39%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.486); catalogued as rs1433400825, COSV52884028; called by muse, mutect2, varscan2
- PTPRN2 | c.2936A>G p.E979G | Missense Mutation (SNP) | VAF 119/358 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs377060293; called by muse, mutect2, varscan2
- RYR2 | c.3860A>G p.Q1287R | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs1312473874; called by muse, varscan2
- RYR2 | c.10158G>T p.K3386N | Missense Mutation (SNP) | VAF 50/356 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.367); catalogued as COSV63659149, COSV63691221; called by muse, mutect2, varscan2
- SCN1A | c.3074A>T p.Y1025F (on ENST00000303395 / NM_001202435.3; = p.Y1014F on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 34/111 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as rs752532497; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SELP | c.1530C>A p.C510* | Nonsense Mutation (SNP) | VAF 58/94 reads (62%) | catalogued as COSV55252821; called by muse, mutect2, varscan2
- SF3B6 | c.366T>A p.D122E | Missense Mutation (SNP) | VAF 125/334 reads (37%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs773270588; called by muse, mutect2, varscan2
- SIPA1L1 | c.3267G>A p.M1089I | Missense Mutation (SNP) | VAF 177/562 reads (31%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs34108937; called by muse, mutect2, varscan2
- SLC1A6 | c.119G>A p.R40H | Missense Mutation (SNP) | VAF 148/400 reads (37%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs540964903, COSV55669653, COSV55671594; called by muse, mutect2, varscan2
- SLC45A2 | c.59G>T p.G20V | Missense Mutation (SNP) | VAF 179/677 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.035); catalogued as COSV56873134; called by muse, mutect2, varscan2
- SLC9C2 | c.1550T>A p.I517K | Missense Mutation (SNP) | VAF 105/195 reads (54%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.844); catalogued as COSV62945354; called by muse, mutect2, varscan2
- SLITRK2 | c.40G>C p.A14P | Missense Mutation (SNP) | VAF 69/91 reads (76%) | SIFT deleterious (0.01); PolyPhen benign (0.332); catalogued as rs1556943693; called by muse, mutect2, varscan2
- SMCHD1 | c.3109G>A p.A1037T | Missense Mutation (SNP) | VAF 99/439 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); catalogued as COSV55266562; called by muse, mutect2, varscan2
- SMG1 | c.5677G>A p.E1893K | Missense Mutation (SNP) | VAF 134/231 reads (58%) | SIFT tolerated (0.69); PolyPhen benign (0.05); catalogued as COSV67169898; called by muse, mutect2, varscan2
- SPART | c.1837G>A p.V613M | Missense Mutation (SNP) | VAF 342/484 reads (71%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as rs574448043; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SQOR | c.865-2A>G p.X289_splice | Splice Site (SNP) | VAF 57/105 reads (54%) | catalogued as COSV52940523; called by muse, mutect2, varscan2
- SRP72 | c.1502+1G>A p.X501_splice | Splice Site (SNP) | VAF 13/156 reads (8%) | catalogued as rs750937171, COSV61378720; called by muse, mutect2
- SYN2 | c.1685A>T p.D562V | Missense Mutation (SNP) | VAF 114/217 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.691); catalogued as rs767472530; called by muse, mutect2, varscan2
- SYNDIG1L | c.52C>A p.H18N | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.25); PolyPhen benign (0.143); catalogued as COSV100526432, COSV59046832; called by muse, mutect2
- TAAR1 | c.304A>G p.T102A | Missense Mutation (SNP) | VAF 136/721 reads (19%) | SIFT tolerated (0.28); PolyPhen benign (0.005); catalogued as rs1365171193; called by muse, mutect2, varscan2
- TET2 | c.5131A>G p.I1711V | Missense Mutation (SNP) | VAF 106/173 reads (61%) | SIFT tolerated (0.17); PolyPhen benign (0.09); catalogued as rs1468900249; called by muse, mutect2, varscan2
- TIFAB | c.139C>T p.Q47* | Nonsense Mutation (SNP) | VAF 61/94 reads (65%) | catalogued as COSV72345884; called by muse, mutect2, varscan2
- TIPARP | c.551A>G p.Y184C | Missense Mutation (SNP) | VAF 178/504 reads (35%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.431); catalogued as rs1182371185; called by muse, mutect2, varscan2
- TLR4 | c.1492T>A p.L498M (on ENST00000355622 / NM_138554.5; = p.L458M on NM_003266.4) | Missense Mutation (SNP) | VAF 48/387 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62923526; called by muse, mutect2, varscan2
- TMEM209 | c.173T>G p.V58G | Missense Mutation (SNP) | VAF 73/244 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.336); catalogued as COSV52832982; called by muse, mutect2, varscan2
- TPO | c.1682C>T p.T561M | Missense Mutation (SNP) | VAF 70/614 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs200475577, CM165666, COSV61098733; called by muse, mutect2, varscan2
- TTN | c.91600T>C p.Y30534H (on ENST00000591111; = p.Y23110H on NM_003319.4) | Missense Mutation (SNP) | VAF 210/561 reads (37%) | PolyPhen probably damaging (0.999); catalogued as rs2555814; called by muse, mutect2, varscan2
- TTN | c.38720G>T p.G12907V (on ENST00000591111; = p.G5483V on NM_003319.4) | Missense Mutation (SNP) | VAF 91/285 reads (32%) | PolyPhen possibly damaging (0.893); catalogued as COSV59953809; called by muse, mutect2, varscan2
- TTN | c.9154T>C p.Y3052H (on ENST00000591111; = p.Y3006H on NM_003319.4) | Missense Mutation (SNP) | VAF 138/402 reads (34%) | PolyPhen benign (0.006); catalogued as rs763833161; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- USH1G | c.1264T>C p.S422P | Missense Mutation (SNP) | VAF 181/501 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1206146354; called by muse, mutect2, varscan2
- UST | c.841G>A p.V281M | Missense Mutation (SNP) | VAF 108/339 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs754638085, COSV66548124; called by muse, mutect2, varscan2
- UTP20 | c.3860A>G p.N1287S | Missense Mutation (SNP) | VAF 231/308 reads (75%) | SIFT tolerated (0.97); PolyPhen benign (0); catalogued as COSV55377711; called by muse, mutect2, varscan2
- VWA3A | c.2867T>C p.L956S | Missense Mutation (SNP) | VAF 57/106 reads (54%) | SIFT deleterious (0); PolyPhen benign (0.221); catalogued as rs775866609, COSV55390560; called by muse, mutect2, varscan2
- YJEFN3 | c.247G>A p.E83K | Missense Mutation (SNP) | VAF 73/201 reads (36%) | SIFT tolerated (0.17); PolyPhen benign (0.006); catalogued as rs757323367; called by muse, mutect2, varscan2
- ZFHX4 | c.4174del p.R1392Vfs*49 | Frame Shift Del (DEL) | VAF 82/282 reads (29%) | catalogued as COSV51498826; called by mutect2, pindel, varscan2
- ZFHX4 | c.4531G>T p.D1511Y | Missense Mutation (SNP) | VAF 103/266 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as COSV50698588; called by muse, mutect2, varscan2
- ZIC1 | c.745A>G p.M249V | Missense Mutation (SNP) | VAF 134/403 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as COSV51550519; called by muse, mutect2, varscan2
- A1CF | c.1287G>T p.M429I (on ENST00000373993 / NM_138932.2; = p.M421I on NM_014576.4) | Missense Mutation (SNP) | VAF 127/242 reads (52%) | SIFT tolerated (0.16); PolyPhen benign (0.23); called by muse, mutect2, varscan2
- ABCA8 | c.2879C>G p.S960* | Nonsense Mutation (SNP) | VAF 12/388 reads (3%) | called by muse, mutect2
- ABTB2 | c.1756-1G>T p.X586_splice | Splice Site (SNP) | VAF 88/216 reads (41%) | called by muse, mutect2, varscan2
- ACCS | c.544T>A p.C182S | Missense Mutation (SNP) | VAF 68/181 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- ACSL6 | c.1856G>C p.G619A (on ENST00000379240; = p.G644A on NM_015256.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 75/132 reads (57%) | SIFT deleterious (0.03); PolyPhen benign (0.251); called by muse, mutect2, varscan2
- ADGRA2 | c.3061G>T p.A1021S | Missense Mutation (SNP) | VAF 105/179 reads (59%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.913); called by muse, mutect2, varscan2
- AKAP1 | c.2013dup p.G672Wfs*35 | Frame Shift Ins (INS) | VAF 85/269 reads (32%) | called by mutect2, pindel, varscan2
- AL121899.2 | c.1330A>G p.T444A | Missense Mutation (SNP) | VAF 127/416 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AL133500.1 | c.1365T>A p.S455R | Missense Mutation (SNP) | VAF 86/336 reads (26%) | SIFT deleterious, low confidence (0.01); called by muse, mutect2, varscan2
- ALKBH2 | c.167G>T p.S56I | Missense Mutation (SNP) | VAF 194/251 reads (77%) | SIFT tolerated (0.07); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- ANKRD30B | c.2042A>T p.N681I | Missense Mutation (SNP) | VAF 186/403 reads (46%) | SIFT deleterious (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- AP1B1 | c.1079A>G p.E360G | Missense Mutation (SNP) | VAF 96/255 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- AP3D1 | c.856G>A p.V286M | Missense Mutation (SNP) | VAF 107/316 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- APOB | c.12278C>A p.T4093K | Missense Mutation (SNP) | VAF 24/79 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- APOB | c.8051T>C p.L2684P | Missense Mutation (SNP) | VAF 82/249 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); called by muse, mutect2, varscan2
- APOH | c.445A>C p.T149P | Missense Mutation (SNP) | VAF 67/193 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- ASTN1 | c.3386A>T p.N1129I | Missense Mutation (SNP) | VAF 38/219 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.246); called by muse, mutect2, varscan2
- ATM | c.7763C>G p.P2588R | Missense Mutation (SNP) | VAF 128/247 reads (52%) | SIFT tolerated (0.1); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ATXN7L2 | c.1466C>A p.T489N | Missense Mutation (SNP) | VAF 57/105 reads (54%) | SIFT tolerated (0.07); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- BARX1 | c.205C>A p.P69T | Missense Mutation (SNP) | VAF 138/256 reads (54%) | SIFT deleterious (0.01); PolyPhen benign (0.185); called by muse, mutect2, varscan2
- BCL9L | c.2755A>G p.I919V | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT tolerated (0.79); PolyPhen benign (0.007); called by muse, mutect2
- BICD2 | c.126G>T p.Q42H | Missense Mutation (SNP) | VAF 289/570 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); called by muse, mutect2, varscan2
- CACNB2 | c.245C>A p.S82Y (on ENST00000324631 / NM_201596.3; = p.S27Y on NM_000724.4) | Missense Mutation (SNP) | VAF 208/613 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CADM1 | c.665T>A p.V222E | Missense Mutation (SNP) | VAF 149/299 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CALB1 | c.62T>A p.L21H | Missense Mutation (SNP) | VAF 158/353 reads (45%) | SIFT tolerated (0.24); PolyPhen benign (0); called by muse, mutect2, varscan2
- CCDC190 | c.13A>G p.M5V | Missense Mutation (SNP) | VAF 31/157 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- CCDC25 | c.393C>A p.N131K | Missense Mutation (SNP) | VAF 156/265 reads (59%) | SIFT deleterious (0.03); PolyPhen benign (0.265); called by muse, mutect2, varscan2
- CD209 | c.1201C>A p.P401T | Missense Mutation (SNP) | VAF 190/247 reads (77%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); called by muse, mutect2, varscan2
- CD79A | c.562T>C p.Y188H | Missense Mutation (SNP) | VAF 171/295 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CDC73 | c.1327G>A p.V443I | Missense Mutation (SNP) | VAF 89/786 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.688); called by muse, mutect2, varscan2
- CDH18 | c.2151G>T p.K717N | Missense Mutation (SNP) | VAF 120/440 reads (27%) | SIFT tolerated (0.61); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CDHR2 | c.2296C>A p.L766M | Missense Mutation (SNP) | VAF 41/63 reads (65%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CDK8 | c.587C>A p.T196K | Missense Mutation (SNP) | VAF 88/181 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CDR1 | c.705G>T p.K235N | Missense Mutation (SNP) | VAF 93/123 reads (76%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- CEP295 | c.5532C>A p.N1844K | Missense Mutation (SNP) | VAF 18/205 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.111); called by muse, mutect2
- CES2 | c.728C>T p.S243F | Missense Mutation (SNP) | VAF 16/368 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.619); called by muse, mutect2
- CFAP44 | c.3810G>T p.Q1270H | Missense Mutation (SNP) | VAF 327/455 reads (72%) | SIFT tolerated (0.18); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CFAP46 | c.4513C>A p.L1505I | Missense Mutation (SNP) | VAF 25/81 reads (31%) | SIFT tolerated (0.71); PolyPhen possibly damaging (0.543); called by muse, mutect2, varscan2
- CHD1L | c.2513T>C p.V838A | Missense Mutation (SNP) | VAF 25/138 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, varscan2
- CHRM3 | c.145T>A p.F49I | Missense Mutation (SNP) | VAF 71/620 reads (11%) | SIFT tolerated (0.37); PolyPhen benign (0); called by muse, mutect2, varscan2
- CLDN12 | c.96C>A p.N32K | Missense Mutation (SNP) | VAF 117/358 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- CLIP1 | c.385C>T p.Q129* | Nonsense Mutation (SNP) | VAF 255/322 reads (79%) | called by muse, mutect2, varscan2
- CNTN6 | c.1016G>C p.C339S | Missense Mutation (SNP) | VAF 180/274 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COG2 | c.827A>G p.Y276C | Missense Mutation (SNP) | VAF 64/448 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); called by muse, mutect2, varscan2
- COL22A1 | c.3476G>A p.G1159E | Missense Mutation (SNP) | VAF 48/92 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); called by muse, mutect2, varscan2
- COL22A1 | c.1873T>C p.S625P | Missense Mutation (SNP) | VAF 59/135 reads (44%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- COP1 | c.1841T>A p.V614D | Missense Mutation (SNP) | VAF 30/157 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- CSMD1 | c.8162G>T p.C2721F (on ENST00000520002; = p.C2720F on NM_033225.6) | Missense Mutation (SNP) | VAF 72/125 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CSMD1 | c.5132A>C p.Q1711P (on ENST00000520002; = p.Q1710P on NM_033225.6) | Missense Mutation (SNP) | VAF 74/146 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- CSMD3 | c.4171A>T p.S1391C (on ENST00000297405 / NM_001363185.1; = p.S1287C on NM_052900.3) | Missense Mutation (SNP) | VAF 162/318 reads (51%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- CSRNP3 | c.170A>C p.E57A | Missense Mutation (SNP) | VAF 76/195 reads (39%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.702); called by muse, mutect2
- CUBN | c.7585A>T p.S2529C | Missense Mutation (SNP) | VAF 139/399 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.86); called by muse, mutect2, varscan2
- CYP11A1 | c.704A>G p.D235G | Missense Mutation (SNP) | VAF 203/356 reads (57%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- CYP26B1 | c.124G>T p.D42Y | Missense Mutation (SNP) | VAF 61/164 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- DAAM1 | c.1045A>G p.R349G | Missense Mutation (SNP) | VAF 55/180 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- DCDC1 | c.3854C>A p.T1285K (on ENST00000597505 / NM_001367979.1; = p.T392K on NM_020869.3) | Missense Mutation (SNP) | VAF 67/204 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DCHS1 | c.1707A>T p.Q569H | Missense Mutation (SNP) | VAF 73/218 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- DHX57 | c.7T>A p.S3T | Missense Mutation (SNP) | VAF 88/225 reads (39%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.162); called by muse, mutect2, varscan2
- DNAH3 | c.308A>G p.H103R | Missense Mutation (SNP) | VAF 185/337 reads (55%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- DNAJC10 | c.1191+2T>C p.X397_splice | Splice Site (SNP) | VAF 65/166 reads (39%) | called by muse, mutect2, varscan2
- DNAJC14 | c.1222A>C p.I408L | Missense Mutation (SNP) | VAF 55/75 reads (73%) | SIFT tolerated (0.4); PolyPhen benign (0); called by muse, mutect2, varscan2
- DNAJC25 | c.858A>G p.I286M | Missense Mutation (SNP) | VAF 158/223 reads (71%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- DONSON | c.680C>G p.S227C | Missense Mutation (SNP) | VAF 111/158 reads (70%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); called by muse, mutect2, varscan2
- DSCAML1 | c.3133+2T>A p.X1045_splice (on ENST00000321322; = p.X985_splice on NM_020693.4) | Splice Site (SNP) | VAF 30/60 reads (50%) | called by muse, mutect2, varscan2
- EBF3 | c.232C>T p.Q78* | Nonsense Mutation (SNP) | VAF 117/371 reads (32%) | called by muse, mutect2, varscan2
- EFHC1 | c.574G>C p.V192L | Missense Mutation (SNP) | VAF 109/199 reads (55%) | SIFT tolerated (0.24); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- EIF4G1 | c.2288G>C p.R763T (on ENST00000346169 / NM_198241.3; = p.R568T on NM_004953.5) | Missense Mutation (SNP) | VAF 197/587 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.674); called by muse, mutect2, varscan2
- EIPR1 | c.1106A>G p.D369G | Missense Mutation (SNP) | VAF 38/131 reads (29%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.918); called by muse, mutect2, varscan2
- ELOC | c.116C>T p.S39L | Missense Mutation (SNP) | VAF 51/162 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.41); called by muse, mutect2, varscan2
- ERN2 | c.605C>A p.A202E | Missense Mutation (SNP) | VAF 63/100 reads (63%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.809); called by muse, mutect2, varscan2
- FAM117B | c.753+1G>A p.X251_splice | Splice Site (SNP) | VAF 50/127 reads (39%) | called by muse, mutect2, varscan2
- FAM135B | c.3540+1G>T p.X1180_splice | Splice Site (SNP) | VAF 36/85 reads (42%) | called by muse, mutect2, varscan2
- FAM161A | c.313G>A p.A105T | Missense Mutation (SNP) | VAF 223/595 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- FAM20C | c.205G>A p.E69K | Missense Mutation (SNP) | VAF 108/265 reads (41%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- FBXO11 | c.2263C>G p.Q755E (on ENST00000403359 / NM_001190274.2; = p.Q671E on NM_025133.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 133/281 reads (47%) | SIFT tolerated (0.17); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- FBXO21 | c.1754A>G p.Y585C (on ENST00000330622 / NM_033624.3; = p.Y578C on NM_015002.3) | Missense Mutation (SNP) | VAF 151/209 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FIGN | c.769G>T p.A257S | Missense Mutation (SNP) | VAF 108/342 reads (32%) | SIFT tolerated (0.81); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FNDC1 | c.3653G>T p.S1218I | Missense Mutation (SNP) | VAF 82/227 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- FOXL2NB | c.188T>A p.M63K | Missense Mutation (SNP) | VAF 281/399 reads (70%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FSIP2 | c.14710T>A p.F4904I | Missense Mutation (SNP) | VAF 43/121 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.514); called by muse, mutect2, varscan2
- FSIP2 | c.16780G>T p.E5594* | Nonsense Mutation (SNP) | VAF 59/164 reads (36%) | called by muse, mutect2, varscan2
- GLB1L2 | c.520T>C p.Y174H | Missense Mutation (SNP) | VAF 64/121 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- GLB1L3 | c.920T>A p.F307Y | Missense Mutation (SNP) | VAF 27/270 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.33); called by muse, mutect2, varscan2
- GLB1L3 | c.1474A>G p.K492E | Missense Mutation (SNP) | VAF 22/210 reads (10%) | SIFT tolerated (0.98); PolyPhen benign (0); called by muse, mutect2, varscan2
- GPR83 | c.813G>T p.M271I | Missense Mutation (SNP) | VAF 212/388 reads (55%) | SIFT deleterious (0.02); PolyPhen benign (0); called by muse, mutect2, varscan2
- GREB1L | c.4572T>A p.S1524R | Missense Mutation (SNP) | VAF 310/530 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.663); called by muse, mutect2, varscan2
- GRIN2B | c.1063G>A p.G355S | Missense Mutation (SNP) | VAF 436/642 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- GRM1 | c.213G>C p.R71S | Missense Mutation (SNP) | VAF 180/513 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- GSE1 | c.1415_1433del p.H472Lfs*10 | Frame Shift Del (DEL) | VAF 43/113 reads (38%) | called by mutect2, pindel, varscan2
- GZMH | c.479A>G p.Q160R | Missense Mutation (SNP) | VAF 72/197 reads (37%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.458); called by muse, mutect2, varscan2
- HBG1 | c.314A>T p.K105M | Missense Mutation (SNP) | VAF 121/392 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.702); called by muse, mutect2, varscan2
- HEPACAM | c.22C>A p.L8M | Missense Mutation (SNP) | VAF 193/372 reads (52%) | SIFT tolerated (0.18); PolyPhen benign (0.131); called by muse, mutect2, varscan2
- HHLA2 | c.119T>G p.I40S | Missense Mutation (SNP) | VAF 113/150 reads (75%) | SIFT deleterious (0); PolyPhen benign (0.368); called by muse, mutect2, varscan2
- HS3ST4 | c.1264C>T p.P422S | Missense Mutation (SNP) | VAF 205/344 reads (60%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.614); called by muse, mutect2, varscan2
- HSP90B1 | c.2346G>C p.M782I | Missense Mutation (SNP) | VAF 50/446 reads (11%) | SIFT tolerated (0.41); PolyPhen benign (0); called by muse, mutect2
- IGHE | c.660C>A p.Y220* | Nonsense Mutation (SNP) | VAF 49/160 reads (31%) | called by muse, mutect2, varscan2
- IGKV1-12 | c.101C>A p.S34Y | Missense Mutation (SNP) | VAF 146/808 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.235); called by muse, mutect2
- IGKV5-2 | c.184G>C p.E62Q | Missense Mutation (SNP) | VAF 186/510 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.114); called by muse, mutect2, varscan2
- IGLC7 | c.65A>T p.N22I | Missense Mutation (SNP) | VAF 240/674 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.854); called by muse, mutect2, varscan2
- IL17F | c.304T>G p.C102G | Missense Mutation (SNP) | VAF 153/239 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IMMT | c.1169C>T p.S390L | Missense Mutation (SNP) | VAF 10/200 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.047); called by muse, mutect2
- IMPG2 | c.1559A>T p.E520V | Missense Mutation (SNP) | VAF 206/319 reads (65%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.617); called by muse, mutect2, varscan2
- INTS4 | c.1515-1G>A p.X505_splice | Splice Site (SNP) | VAF 16/352 reads (5%) | called by muse, mutect2
- IRAK3 | c.1687C>A p.P563T | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- IRGQ | c.1291G>T p.V431L | Missense Mutation (SNP) | VAF 62/118 reads (53%) | SIFT deleterious (0.03); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- JAK2 | c.131A>G p.Y44C | Missense Mutation (SNP) | VAF 191/289 reads (66%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KIAA0586 | c.2396A>T p.Q799L (on ENST00000619416 / NM_001244190.2; = p.Q738L on NM_014749.5) | Missense Mutation (SNP) | VAF 42/96 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- KIAA1109 | c.1279G>A p.E427K | Missense Mutation (SNP) | VAF 58/101 reads (57%) | SIFT tolerated (0.49); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- KIAA1549L | c.5080G>T p.V1694L (on ENST00000321505; = p.V1991L on NM_012194.3) | Missense Mutation (SNP) | VAF 67/187 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- KIAA1614 | c.766A>C p.S256R | Missense Mutation (SNP) | VAF 266/414 reads (64%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); called by muse, mutect2, varscan2
- KIAA2012 | c.2188G>A p.E730K | Missense Mutation (SNP) | VAF 94/279 reads (34%) | SIFT tolerated (0.15); called by muse, mutect2, varscan2
- KIF12 | c.1469T>A p.M490K (on ENST00000640217; = p.M352K on NM_138424.1) | Missense Mutation (SNP) | VAF 141/196 reads (72%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.343); called by muse, mutect2, varscan2
- KIF16B | c.3059A>T p.Q1020L | Missense Mutation (SNP) | VAF 60/192 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.075); called by muse, varscan2
- KIF25 | c.775G>A p.E259K | Missense Mutation (SNP) | VAF 104/296 reads (35%) | SIFT tolerated (0.83); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- KLHL34 | c.1781G>A p.G594D | Missense Mutation (SNP) | VAF 69/116 reads (59%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.861); called by muse, mutect2, varscan2
- KMT2D | c.14381A>T p.K4794M | Missense Mutation (SNP) | VAF 147/184 reads (80%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KRBA1 | c.2722G>C p.A908P | Missense Mutation (SNP) | VAF 74/172 reads (43%) | SIFT tolerated (0.21); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- KRIT1 | c.990-2_999del p.X330_splice | Splice Site (DEL) | VAF 78/360 reads (22%) | called by mutect2, pindel, varscan2
- KRTAP19-4 | c.40G>A p.G14S | Missense Mutation (SNP) | VAF 125/339 reads (37%) | SIFT tolerated, low confidence (0.21); PolyPhen possibly damaging (0.881); called by muse, mutect2, varscan2
- KRTAP27-1 | c.424C>A p.P142T | Missense Mutation (SNP) | VAF 221/294 reads (75%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- LILRA2 | c.1379T>C p.L460P (on ENST00000391738 / NM_001130917.3; = p.L443P on NM_006866.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 115/187 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- LPA | c.3809C>A p.T1270K | Missense Mutation (SNP) | VAF 174/525 reads (33%) | SIFT tolerated (0.75); PolyPhen benign (0.236); called by muse, mutect2, varscan2
- LRRC19 | c.31dup p.W11Lfs*16 | Frame Shift Ins (INS) | VAF 63/352 reads (18%) | called by mutect2, pindel, varscan2
- LUZP2 | c.482T>A p.L161Q | Missense Mutation (SNP) | VAF 84/247 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MAGEC1 | c.2999T>G p.L1000R | Missense Mutation (SNP) | VAF 62/89 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- MAGEC3 | c.907G>A p.G303R | Missense Mutation (SNP) | VAF 83/121 reads (69%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- MAK | c.175C>A p.H59N | Missense Mutation (SNP) | VAF 59/156 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- MAPK4 | c.658G>T p.A220S | Missense Mutation (SNP) | VAF 83/151 reads (55%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- MASP1 | c.1338G>A p.M446I | Missense Mutation (SNP) | VAF 237/321 reads (74%) | SIFT tolerated (0.52); PolyPhen benign (0); called by muse, mutect2, varscan2
- MDH1B | c.1280G>C p.W427S | Missense Mutation (SNP) | VAF 61/235 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- MELK | c.929A>G p.Y310C | Missense Mutation (SNP) | VAF 48/131 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- MGAM | c.4496A>T p.E1499V | Missense Mutation (SNP) | VAF 115/324 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.192); called by muse, mutect2, varscan2
- MIA2 | c.787C>T p.H263Y | Missense Mutation (SNP) | VAF 25/255 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.713); called by muse, mutect2
- MROH2B | c.3679G>T p.E1227* | Nonsense Mutation (SNP) | VAF 88/172 reads (51%) | called by muse, mutect2, varscan2
- MUC19 | c.1231C>A p.P411T | Missense Mutation (SNP) | VAF 232/297 reads (78%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.81); called by muse, mutect2, varscan2
- MUC6 | c.3409C>G p.H1137D | Missense Mutation (SNP) | VAF 112/291 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- MYBPC1 | c.2333del p.P778Qfs*6 | Frame Shift Del (DEL) | VAF 249/448 reads (56%) | called by mutect2, pindel, varscan2
- NELL1 | c.2050C>A p.P684T | Missense Mutation (SNP) | VAF 92/255 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- NLRP14 | c.1369G>T p.V457F | Missense Mutation (SNP) | VAF 259/740 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.424); called by muse, mutect2, varscan2
- NOP58 | c.1028A>T p.H343L | Missense Mutation (SNP) | VAF 53/160 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- NOTCH2 | c.1323C>G p.H441Q | Missense Mutation (SNP) | VAF 207/611 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- NOVA2 | c.908C>A p.A303D | Missense Mutation (SNP) | VAF 138/247 reads (56%) | SIFT deleterious (0.04); PolyPhen benign (0.243); called by muse, varscan2
- NR4A2 | c.302A>T p.Q101L | Missense Mutation (SNP) | VAF 144/407 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- OR1M1 | c.639C>A p.C213* | Nonsense Mutation (SNP) | VAF 360/474 reads (76%) | called by mutect2, varscan2
- OR2M2 | c.217C>A p.L73I | Missense Mutation (SNP) | VAF 118/436 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- OR51E1 | c.697C>A p.R233S | Missense Mutation (SNP) | VAF 90/227 reads (40%) | SIFT tolerated (0.88); PolyPhen benign (0.151); called by muse, mutect2, varscan2
- OR51F2 | c.179C>T p.P60L | Missense Mutation (SNP) | VAF 88/224 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- OR5AS1 | c.573C>A p.D191E | Missense Mutation (SNP) | VAF 24/291 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.484); called by muse, mutect2
- OR5D18 | c.169C>A p.H57N | Missense Mutation (SNP) | VAF 13/124 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.12); called by muse, mutect2, varscan2
- OR5H1 | c.121G>T p.G41W | Missense Mutation (SNP) | VAF 155/477 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.54); called by muse, mutect2, varscan2
- P2RY8 | c.682G>T p.G228C | Missense Mutation (SNP) | VAF 171/573 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- PAPPA2 | c.4703G>A p.G1568D | Missense Mutation (SNP) | VAF 55/326 reads (17%) | SIFT tolerated (0.51); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PAX2 | c.44-15_44-8delinsTTTTTTTT | Splice Region (ONP) | VAF 4/47 reads (9%) | called by muse*, pindel
- PAX9 | c.127A>T p.S43C | Missense Mutation (SNP) | VAF 134/374 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PAXBP1 | c.1757A>C p.E586A | Missense Mutation (SNP) | VAF 63/191 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- PCBP1 | c.751A>C p.M251L | Missense Mutation (SNP) | VAF 129/339 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PDE1C | c.349A>G p.M117V | Missense Mutation (SNP) | VAF 106/291 reads (36%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.525); called by muse, mutect2, varscan2
- PDE6B | c.348C>A p.D116E | Missense Mutation (SNP) | VAF 48/83 reads (58%) | SIFT tolerated (0.32); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PEAR1 | c.2153C>A p.P718Q | Missense Mutation (SNP) | VAF 116/229 reads (51%) | SIFT tolerated (0.19); PolyPhen benign (0.107); called by muse, mutect2, varscan2
- PEX5 | c.1369C>A p.R457S (on ENST00000420616; = p.R449S on NM_000319.5) | Missense Mutation (SNP) | VAF 393/529 reads (74%) | SIFT tolerated (0.62); PolyPhen benign (0.105); called by muse, mutect2, varscan2
- PIMREG | c.395C>T p.P132L | Missense Mutation (SNP) | VAF 156/272 reads (57%) | SIFT tolerated (0.09); PolyPhen benign (0.072); called by muse, mutect2, varscan2
- PLCB1 | c.247-1G>T p.X83_splice | Splice Site (SNP) | VAF 40/169 reads (24%) | called by muse, mutect2, varscan2
- PLXNA4 | c.5518C>T p.H1840Y | Missense Mutation (SNP) | VAF 84/292 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); called by muse, varscan2
- PPP1R3A | c.712C>T p.P238S | Missense Mutation (SNP) | VAF 54/139 reads (39%) | SIFT tolerated (0.24); PolyPhen benign (0.137); called by muse, mutect2, varscan2
- PROKR1 | c.205C>A p.L69M | Missense Mutation (SNP) | VAF 127/336 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- PRR36 | c.2735C>T p.T912M | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT tolerated (0.35); called by muse, mutect2
- PTH2R | c.117G>C p.R39S | Missense Mutation (SNP) | VAF 50/142 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- PTPN12 | c.384C>T p.I128= | Splice Region (SNP) | VAF 31/288 reads (11%) | called by muse, mutect2, varscan2
- PTPRM | c.4160T>A p.V1387E | Missense Mutation (SNP) | VAF 98/196 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- PXDNL | c.2332C>G p.P778A | Missense Mutation (SNP) | VAF 27/146 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PYROXD1 | c.1159G>T p.A387S | Missense Mutation (SNP) | VAF 157/217 reads (72%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- PZP | c.1583C>G p.S528* | Nonsense Mutation (SNP) | VAF 28/222 reads (13%) | called by muse, mutect2, varscan2
- RASAL1 | c.1213G>C p.E405Q | Missense Mutation (SNP) | VAF 7/8 reads (88%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- RASAL3 | c.856G>A p.E286K | Missense Mutation (SNP) | VAF 136/382 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); called by muse, mutect2, varscan2
- RELN | c.1716A>G p.I572M | Missense Mutation (SNP) | VAF 192/508 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.388); called by muse, mutect2, varscan2
- RGPD3 | c.3683C>A p.A1228E | Missense Mutation (SNP) | VAF 350/934 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.172); called by muse, mutect2, varscan2
- RHBG | c.237G>A p.M79I | Missense Mutation (SNP) | VAF 36/209 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.615); called by muse, mutect2, varscan2
- RIMS1 | c.1433C>A p.P478H | Missense Mutation (SNP) | VAF 269/696 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RNF135 | c.694G>T p.A232S | Missense Mutation (SNP) | VAF 232/732 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- RYR2 | c.187T>C p.S63P | Missense Mutation (SNP) | VAF 344/541 reads (64%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.745); called by muse, mutect2, varscan2
- SAMD9L | c.1318T>C p.W440R | Missense Mutation (SNP) | VAF 138/364 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.568); called by muse, mutect2, varscan2
- SAP25 | c.433G>A p.A145T (on ENST00000538735; = p.A243T on NM_001168682.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- SCN5A | c.3919G>C p.A1307P (on ENST00000333535 / NM_198056.3; = p.A1306P on NM_000335.5) | Missense Mutation (SNP) | VAF 78/143 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SCN7A | c.4217A>G p.K1406R | Missense Mutation (SNP) | VAF 100/295 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SHROOM2 | c.1378G>T p.V460L | Missense Mutation (SNP) | VAF 31/41 reads (76%) | SIFT tolerated (0.27); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SLC17A6 | c.315C>G p.H105Q | Missense Mutation (SNP) | VAF 110/284 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.102); called by mutect2, varscan2
- SLC22A31 | c.392G>T p.G131V | Missense Mutation (SNP) | VAF 110/184 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- SLC26A4 | c.1576A>G p.S526G | Missense Mutation (SNP) | VAF 191/574 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLITRK3 | c.1060G>T p.G354C | Missense Mutation (SNP) | VAF 127/380 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- SNTG1 | c.1438C>T p.H480Y | Missense Mutation (SNP) | VAF 187/330 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); called by muse, varscan2
- SPART | c.1048A>G p.I350V | Missense Mutation (SNP) | VAF 363/493 reads (74%) | SIFT tolerated (0.2); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- SRGAP1 | c.374T>A p.V125E | Missense Mutation (SNP) | VAF 124/183 reads (68%) | SIFT deleterious (0); PolyPhen possibly damaging (0.703); called by muse, mutect2, varscan2
- SRSF1 | c.344C>G p.P115R | Missense Mutation (SNP) | VAF 58/214 reads (27%) | SIFT tolerated (0.05); PolyPhen benign (0.413); called by muse, mutect2, varscan2
- STARD9 | c.7829A>T p.E2610V | Missense Mutation (SNP) | VAF 137/227 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); called by muse, mutect2, varscan2
- SUMF1 | c.899A>T p.E300V | Missense Mutation (SNP) | VAF 213/408 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SYNE1 | c.11423A>T p.H3808L (on ENST00000367255 / NM_182961.4; = p.H3793L on NM_033071.3) | Missense Mutation (SNP) | VAF 164/469 reads (35%) | SIFT tolerated (0.14); PolyPhen benign (0.33); called by muse, mutect2, varscan2
- SYNE1 | c.7888G>C p.E2630Q (on ENST00000367255 / NM_182961.4; = p.E2637Q on NM_033071.3) | Missense Mutation (SNP) | VAF 189/558 reads (34%) | SIFT tolerated (0.15); PolyPhen benign (0.376); called by muse, mutect2, varscan2
- SYT16 | c.458G>T p.G153V | Missense Mutation (SNP) | VAF 60/161 reads (37%) | SIFT tolerated (0.14); PolyPhen benign (0.154); called by muse, mutect2, varscan2
- SYTL4 | c.1030A>T p.I344F | Missense Mutation (SNP) | VAF 76/101 reads (75%) | SIFT deleterious (0); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- TAAR6 | c.113T>A p.V38E | Missense Mutation (SNP) | VAF 137/515 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.568); called by muse, mutect2, varscan2
- TAFA1 | c.88A>G p.T30A | Missense Mutation (SNP) | VAF 92/182 reads (51%) | SIFT tolerated (0.54); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TBX20 | c.729G>T p.L243F | Missense Mutation (SNP) | VAF 122/385 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.908); called by muse, mutect2, varscan2
- TDRD3 | c.309A>T p.Q103H | Missense Mutation (SNP) | VAF 105/133 reads (79%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.758); called by muse, mutect2, varscan2
- TERB1 | c.1517G>T p.R506M | Missense Mutation (SNP) | VAF 154/272 reads (57%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.459); called by muse, mutect2, varscan2
- TEX13A | c.1155T>A p.C385* | Nonsense Mutation (SNP) | VAF 130/165 reads (79%) | called by muse, mutect2, varscan2
- TEX13C | c.1420G>T p.A474S | Missense Mutation (SNP) | VAF 258/344 reads (75%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- THRA | c.683G>A p.R228H | Missense Mutation (SNP) | VAF 151/338 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- TMEM45A | c.358G>T p.V120L | Missense Mutation (SNP) | VAF 381/529 reads (72%) | SIFT tolerated (1); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- TNC | c.6549G>C p.E2183D | Missense Mutation (SNP) | VAF 168/241 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TPGS2 | c.598_611del p.L200Vfs*11 | Frame Shift Del (DEL) | VAF 74/188 reads (39%) | called by mutect2, pindel, varscan2
- TRIM46 | c.823A>G p.T275A | Missense Mutation (SNP) | VAF 42/307 reads (14%) | SIFT tolerated (0.35); PolyPhen benign (0.023); called by muse, mutect2
- TRIM51GP | c.126C>A p.N42K | Missense Mutation (SNP) | VAF 167/542 reads (31%) | SIFT tolerated (0.2); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- TRIML1 | c.72C>G p.S24R | Missense Mutation (SNP) | VAF 59/96 reads (61%) | SIFT tolerated (0.11); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- TRIO | c.7601A>G p.E2534G | Missense Mutation (SNP) | VAF 65/223 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.676); called by muse, mutect2, varscan2
- TRPM3 | c.2783C>T p.S928L (on ENST00000357533 / NM_001366142.2; = p.S771L on NM_020952.6) | Missense Mutation (SNP) | VAF 57/196 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.838); called by muse, varscan2
- TTLL12 | c.836A>T p.Y279F | Missense Mutation (SNP) | VAF 31/79 reads (39%) | SIFT tolerated (0.84); PolyPhen benign (0); called by muse, mutect2, varscan2
- TTN | c.88126C>A p.P29376T (on ENST00000591111; = p.P21952T on NM_003319.4) | Missense Mutation (SNP) | VAF 221/611 reads (36%) | PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TTN | c.39172T>A p.S13058T (on ENST00000591111; = p.S5634T on NM_003319.4) | Missense Mutation (SNP) | VAF 53/173 reads (31%) | PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- TTN | c.34291G>T p.V11431L (on ENST00000591111; = p.V12494L on NM_001267550.2) | Missense Mutation (SNP) | VAF 94/492 reads (19%) | PolyPhen benign (0); called by muse, mutect2, varscan2
- TTYH3 | c.155C>A p.A52D | Missense Mutation (SNP) | VAF 93/236 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.462); called by muse, mutect2, varscan2
- TXNDC5 | c.317A>T p.Y106F | Missense Mutation (SNP) | VAF 134/353 reads (38%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- U2SURP | c.45+1G>T p.X15_splice | Splice Site (SNP) | VAF 319/422 reads (76%) | called by muse, mutect2, varscan2
- VEPH1 | c.443T>C p.M148T | Missense Mutation (SNP) | VAF 151/435 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- WDR70 | c.386A>T p.K129I | Missense Mutation (SNP) | VAF 145/322 reads (45%) | SIFT tolerated (0.15); PolyPhen benign (0); called by muse, mutect2, varscan2
- WNK1 | c.2766G>T p.M922I | Missense Mutation (SNP) | VAF 173/230 reads (75%) | SIFT tolerated (0.27); PolyPhen benign (0); called by muse, mutect2, varscan2
- XIAP | c.51C>G p.I17M | Missense Mutation (SNP) | VAF 89/126 reads (71%) | SIFT tolerated (0.18); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ZC3H6 | c.1576G>A p.V526I | Missense Mutation (SNP) | VAF 141/393 reads (36%) | SIFT tolerated (0.4); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZDHHC11B | c.796A>G p.M266V | Missense Mutation (SNP) | VAF 68/842 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.187); called by muse, mutect2
- ZFR2 | c.634T>G p.S212A | Missense Mutation (SNP) | VAF 105/146 reads (72%) | SIFT deleterious (0.01); PolyPhen benign (0.426); called by muse, mutect2, varscan2
- ZNF292 | c.4847G>T p.R1616I | Missense Mutation (SNP) | VAF 124/404 reads (31%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- ZNF426 | c.421A>T p.N141Y | Missense Mutation (SNP) | VAF 80/111 reads (72%) | SIFT deleterious (0.01); PolyPhen benign (0.36); called by muse, mutect2, varscan2
- ZNF492 | c.1444T>A p.C482S | Missense Mutation (SNP) | VAF 107/294 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); called by muse, mutect2, varscan2
- ZNF564 | c.121G>T p.A41S | Missense Mutation (SNP) | VAF 83/255 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.734); called by muse, mutect2, varscan2
- ZNF611 | c.1408G>T p.A470S | Missense Mutation (SNP) | VAF 48/98 reads (49%) | SIFT tolerated (0.34); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- ZNF649 | c.1127G>A p.C376Y | Missense Mutation (SNP) | VAF 72/126 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF71 | c.846C>G p.N282K | Missense Mutation (SNP) | VAF 77/118 reads (65%) | SIFT tolerated (0.26); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- ZNF786 | c.96A>T p.E32D | Missense Mutation (SNP) | VAF 83/214 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ZW10 | c.1504G>A p.D502N | Missense Mutation (SNP) | VAF 81/145 reads (56%) | SIFT tolerated (0.34); PolyPhen benign (0.145); called by muse, varscan2
- ACSL6 | c.1857A>T p.G619= (on ENST00000379240; = p.G644= on NM_015256.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 74/131 reads (56%) | called by muse, mutect2, varscan2
- ADRA1A | c.1260C>A p.T420= | Silent (SNP) | VAF 59/118 reads (50%) | called by muse, mutect2, varscan2
- ARFGEF3 | c.1521C>T p.V507= | Silent (SNP) | VAF 20/708 reads (3%) | called by muse, mutect2
- ARSI | c.1401C>T p.I467= | Silent (SNP) | VAF 71/119 reads (60%) | called by muse, mutect2, varscan2
- ATP6V1B2 | c.1278T>C p.Y426= | Silent (SNP) | VAF 79/138 reads (57%) | called by muse, mutect2, varscan2
- ATXN10 | c.765G>T p.T255= | Silent (SNP) | VAF 146/449 reads (33%) | called by muse, mutect2, varscan2
- BBS9 | c.1194A>G p.S398= | Silent (SNP) | VAF 90/268 reads (34%) | catalogued as rs1446098820; called by muse, mutect2, varscan2
- BCL11A | c.2175C>T p.V725= (on ENST00000335712 / NM_001365609.1; = p.V759= on NM_022893.4) | Silent (SNP) | VAF 144/391 reads (37%) | called by muse, mutect2, varscan2
- C14orf180 | c.465C>T p.R155= | Silent (SNP) | VAF 87/218 reads (40%) | catalogued as rs368551851; called by muse, mutect2, varscan2
- CAPN13 | c.843A>G p.E281= | Silent (SNP) | VAF 80/261 reads (31%) | catalogued as rs1347220430; called by muse, mutect2
- CASP8AP2 | c.4539A>C p.T1513= | Silent (SNP) | VAF 99/265 reads (37%) | called by muse, mutect2, varscan2
- CDH18 | c.1371A>C p.T457= | Silent (SNP) | VAF 47/112 reads (42%) | called by muse, mutect2, varscan2
- CDON | c.3774C>T p.P1258= (on ENST00000392693 / NM_001243597.2; = p.P1235= on NM_016952.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 77/423 reads (18%) | catalogued as rs762266136, COSV55003576, COSV99701979; called by muse, mutect2, varscan2
- COL12A1 | c.309T>C p.S103= | Silent (SNP) | VAF 87/214 reads (41%) | called by muse, mutect2, varscan2
- CTNND2 | c.1323G>A p.Q441= | Silent (SNP) | VAF 79/258 reads (31%) | catalogued as COSV58872313; called by muse, mutect2, varscan2
- CTTNBP2 | c.238C>T p.L80= | Silent (SNP) | VAF 130/344 reads (38%) | catalogued as COSV99352904; called by muse, mutect2, varscan2
- DNAH6 | c.12144C>T p.D4048= | Silent (SNP) | VAF 67/192 reads (35%) | called by muse, mutect2, varscan2
- DNTT | c.867G>A p.Q289= | Silent (SNP) | VAF 7/121 reads (6%) | called by muse, mutect2
- DUOX1 | c.2319C>T p.S773= | Silent (SNP) | VAF 29/51 reads (57%) | catalogued as rs746407999; called by muse, mutect2, varscan2
- DYNC1H1 | c.8931G>A p.R2977= | Silent (SNP) | VAF 255/688 reads (37%) | called by muse, mutect2, varscan2
- DZIP3 | c.3069A>G p.A1023= | Silent (SNP) | VAF 79/248 reads (32%) | catalogued as rs1196842683; called by muse, mutect2, varscan2
- EIF3B | c.1713A>G p.E571= | Silent (SNP) | VAF 54/168 reads (32%) | called by muse, mutect2, varscan2
- EPB41L5 | c.1914G>A p.L638= | Silent (SNP) | VAF 82/272 reads (30%) | catalogued as COSV55355101; called by muse, mutect2, varscan2
- FAAH2 | c.1416T>G p.A472= | Silent (SNP) | VAF 135/192 reads (70%) | called by muse, mutect2, varscan2
- FAM186A | c.5808G>A p.P1936= | Silent (SNP) | VAF 146/184 reads (79%) | catalogued as rs965506725; called by muse, mutect2, varscan2
- FAM71E2 | c.519G>T p.L173= | Silent (SNP) | VAF 56/91 reads (62%) | called by muse, mutect2, varscan2
- FAM83B | c.1590G>A p.K530= | Silent (SNP) | VAF 102/176 reads (58%) | called by muse, mutect2, varscan2
- FGFRL1 | c.753G>T p.T251= | Silent (SNP) | VAF 69/106 reads (65%) | catalogued as COSV53256786; called by muse, mutect2, varscan2
- FSIP2 | c.18744T>C p.T6248= | Silent (SNP) | VAF 82/228 reads (36%) | called by muse, mutect2, varscan2
- FUT9 | c.138T>A p.S46= | Silent (SNP) | VAF 73/138 reads (53%) | called by muse, mutect2, varscan2
- GRIFIN | c.240G>A p.G80= | Silent (SNP) | VAF 20/49 reads (41%) | catalogued as rs1221040289; called by muse, mutect2, varscan2
- HS6ST1 | c.603T>C p.G201= | Silent (SNP) | VAF 40/390 reads (10%) | catalogued as COSV52126972; called by muse, varscan2
- ID1 | c.354C>T p.P118= | Silent (SNP) | VAF 105/271 reads (39%) | catalogued as rs11545371, COSV65888744; called by muse, mutect2, varscan2
- JAKMIP1 | c.853C>A p.R285= | Silent (SNP) | VAF 6/100 reads (6%) | catalogued as COSV99289663; called by muse, mutect2
- KCNT2 | c.2418C>A p.T806= | Silent (SNP) | VAF 49/277 reads (18%) | catalogued as COSV99654631; called by muse, mutect2, varscan2
- KIAA0408 | c.450G>C p.L150= | Silent (SNP) | VAF 58/191 reads (30%) | called by muse, mutect2, varscan2
- KIF19 | c.1119C>G p.G373= | Silent (SNP) | VAF 115/283 reads (41%) | catalogued as rs371257733; called by muse, mutect2, varscan2
- LILRA1 | c.852G>C p.L284= | Silent (SNP) | VAF 167/349 reads (48%) | called by muse, mutect2, varscan2
- MAGEE1 | c.894C>A p.P298= | Silent (SNP) | VAF 202/288 reads (70%) | called by muse, mutect2, varscan2
- MAGEL2 | c.1665G>T p.P555= | Silent (SNP) | VAF 34/54 reads (63%) | catalogued as rs768084923, COSV100046094; called by muse, mutect2, varscan2
- MARVELD3 | c.24C>A p.R8= | Silent (SNP) | VAF 41/68 reads (60%) | called by muse, mutect2, varscan2
- MAT1A | c.699C>T p.A233= | Silent (SNP) | VAF 14/442 reads (3%) | called by muse, mutect2
- MDN1 | c.12828C>A p.A4276= | Silent (SNP) | VAF 54/152 reads (36%) | catalogued as rs1428882969; called by muse, mutect2, varscan2
- MUC12 | c.13539C>A p.A4513= (on ENST00000379442; = p.A4370= on NM_001164462.1) | Silent (SNP) | VAF 16/149 reads (11%) | called by mutect2, varscan2
- MUC2 | c.1047C>T p.H349= | Silent (SNP) | VAF 14/312 reads (4%) | catalogued as rs748567884; called by muse, mutect2
- MUC4 | c.7467A>G p.V2489= | Silent (SNP) | VAF 193/1541 reads (13%) | catalogued as rs768611716; called by muse, mutect2, varscan2
- MYO15A | c.3051C>G p.T1017= | Silent (SNP) | VAF 12/220 reads (5%) | catalogued as COSV52758557; called by muse, mutect2
- NLRP3 | c.1668G>A p.V556= | Silent (SNP) | VAF 115/1382 reads (8%) | called by muse, mutect2
- NRP2 | c.1848C>T p.P616= | Silent (SNP) | VAF 210/562 reads (37%) | called by muse, mutect2, varscan2
- NRXN3 | c.1782C>A p.L594= (on ENST00000335750 / NM_001330195.2; = p.L221= on NM_004796.6) | Silent (SNP) | VAF 160/481 reads (33%) | called by muse, mutect2, varscan2
- NUP62 | c.561G>C p.T187= | Silent (SNP) | VAF 181/296 reads (61%) | catalogued as COSV61312229; called by muse, mutect2, varscan2
- OR10G8 | c.408T>A p.T136= | Silent (SNP) | VAF 36/308 reads (12%) | called by muse, mutect2, varscan2
- OR2M7 | c.174C>G p.P58= | Silent (SNP) | VAF 46/311 reads (15%) | called by muse, mutect2, varscan2
- OR4A16 | c.498C>T p.I166= | Silent (SNP) | VAF 144/277 reads (52%) | catalogued as rs868783544, COSV59045457; called by muse, mutect2, varscan2
- OR4C12 | c.345G>C p.V115= | Silent (SNP) | VAF 33/284 reads (12%) | catalogued as COSV100078612; called by muse, mutect2, varscan2
- OR4C15 | c.615C>A p.G205= (on ENST00000314644; = p.G151= on NM_001001920.2) | Silent (SNP) | VAF 119/248 reads (48%) | catalogued as rs763191657, COSV100115932, COSV58954929; called by muse, mutect2, varscan2
- OR5T2 | c.870T>C p.Y290= | Silent (SNP) | VAF 47/95 reads (49%) | called by muse, mutect2, varscan2
- OTUD6A | c.447C>T p.D149= | Silent (SNP) | VAF 137/185 reads (74%) | catalogued as rs1217807861; called by muse, mutect2, varscan2
- PEAR1 | c.195C>T p.C65= | Silent (SNP) | VAF 100/201 reads (50%) | catalogued as rs1374648304, COSV52771358; called by muse, mutect2, varscan2
- PIK3CG | c.2253G>C p.S751= | Silent (SNP) | VAF 117/318 reads (37%) | catalogued as COSV100783333; called by muse, varscan2
- PLEKHA1 | c.1068C>T p.F356= | Silent (SNP) | VAF 22/589 reads (4%) | catalogued as COSV64569921; called by muse, mutect2
- POM121L12 | c.258C>T p.P86= | Silent (SNP) | VAF 71/241 reads (29%) | catalogued as rs376672272; called by muse, mutect2, varscan2
- PRMT5 | c.579G>T p.R193= | Silent (SNP) | VAF 129/396 reads (33%) | catalogued as rs749416572; called by muse, varscan2
- PRNP | c.45A>G p.T15= | Silent (SNP) | VAF 177/432 reads (41%) | called by muse, mutect2, varscan2
- PTCHD1 | c.27C>T p.G9= | Silent (SNP) | VAF 66/90 reads (73%) | called by muse, mutect2, varscan2
- RASAL3 | c.336G>A p.E112= | Silent (SNP) | VAF 34/107 reads (32%) | called by muse, mutect2, varscan2
- RBM24 | c.600A>T p.P200= (on ENST00000379052 / NM_001143942.2; = p.P155= on NM_153020.2) | Silent (SNP) | VAF 38/145 reads (26%) | called by muse, mutect2, varscan2
- RFX7 | c.1275T>A p.P425= (on ENST00000559447 / NM_001368074.1; = p.P522= on NM_022841.7 and 1 other RefSeq transcript) | Silent (SNP) | VAF 214/330 reads (65%) | called by muse, mutect2, varscan2
- RGPD4 | c.3090T>A p.T1030= | Silent (SNP) | VAF 286/942 reads (30%) | called by muse, mutect2, varscan2
- RNF139 | c.1620A>G p.L540= | Silent (SNP) | VAF 112/304 reads (37%) | called by muse, mutect2, varscan2
- ROCK1 | c.510G>T p.V170= | Silent (SNP) | VAF 88/396 reads (22%) | called by muse, mutect2, varscan2
- RP1 | c.5376C>T p.A1792= | Silent (SNP) | VAF 123/374 reads (33%) | catalogued as COSV99608191; called by muse, mutect2, varscan2
- RP1 | c.2364A>G p.A788= | Silent (SNP) | VAF 104/276 reads (38%) | catalogued as rs1159287302; called by muse, mutect2, varscan2
- RYR2 | c.9183G>C p.L3061= | Silent (SNP) | VAF 220/346 reads (64%) | called by muse, mutect2, varscan2
- SKAP2 | c.624A>G p.E208= | Silent (SNP) | VAF 71/203 reads (35%) | called by muse, mutect2, varscan2
- SLC30A7 | c.534C>G p.L178= | Silent (SNP) | VAF 9/151 reads (6%) | called by muse, mutect2
- SZT2 | c.1008G>T p.L336= | Silent (SNP) | VAF 192/313 reads (61%) | catalogued as rs934093100, COSV65169658; called by muse, mutect2, varscan2
- TACR1 | c.1110G>A p.E370= | Silent (SNP) | VAF 176/509 reads (35%) | called by muse, mutect2, varscan2
- TBC1D24 | c.546G>T p.T182= | Silent (SNP) | VAF 314/519 reads (61%) | catalogued as rs182825122; called by muse, mutect2, varscan2
- TEX101 | c.588A>T p.G196= (on ENST00000598265 / NM_001130011.3; = p.G214= on NM_031451.4) | Silent (SNP) | VAF 154/277 reads (56%) | called by muse, mutect2, varscan2
- TFEC | c.432C>T p.H144= | Silent (SNP) | VAF 59/214 reads (28%) | called by muse, mutect2, varscan2
- TMIGD2 | c.702G>A p.P234= | Silent (SNP) | VAF 134/183 reads (73%) | catalogued as rs762274173, COSV56667090; called by muse, mutect2, varscan2
- TNR | c.1683G>T p.V561= | Silent (SNP) | VAF 30/232 reads (13%) | called by muse, mutect2, varscan2
- TPO | c.918G>T p.G306= | Silent (SNP) | VAF 177/480 reads (37%) | catalogued as COSV61099336; called by muse, mutect2, varscan2
- TTN | c.44547G>T p.L14849= (on ENST00000591111; = p.L7425= on NM_003319.4) | Silent (SNP) | VAF 47/184 reads (26%) | called by muse, mutect2, varscan2
- TTN | c.37698T>C p.D12566= (on ENST00000591111; = p.D5142= on NM_003319.4) | Silent (SNP) | VAF 150/375 reads (40%) | catalogued as rs1167744371; called by muse, mutect2, varscan2
- UCMA | c.195C>A p.S65= | Silent (SNP) | VAF 72/209 reads (34%) | catalogued as rs755878781; called by muse, mutect2, varscan2
- UNC79 | c.6933T>C p.P2311= (on ENST00000393151 / NM_001346218.2; = p.P2134= on NM_020818.5) | Silent (SNP) | VAF 102/283 reads (36%) | catalogued as rs758486062; called by muse, mutect2, varscan2
- UNC80 | c.8979C>T p.A2993= | Silent (SNP) | VAF 56/125 reads (45%) | called by muse, mutect2, varscan2
- USP32 | c.4074G>A p.L1358= | Silent (SNP) | VAF 77/206 reads (37%) | catalogued as COSV56276525; called by muse, mutect2, varscan2
- VWDE | c.3321A>G p.T1107= | Silent (SNP) | VAF 118/318 reads (37%) | called by muse, mutect2, varscan2
- WASL | c.1410A>G p.A470= | Silent (SNP) | VAF 70/222 reads (32%) | called by muse, mutect2, varscan2
- ZBTB41 | c.864A>G p.E288= | Silent (SNP) | VAF 148/235 reads (63%) | catalogued as rs1464818714; called by muse, mutect2, varscan2
- ZFHX4 | c.2994C>T p.H998= | Silent (SNP) | VAF 138/388 reads (36%) | called by muse, mutect2, varscan2
- ZNF492 | c.891T>A p.T297= | Silent (SNP) | VAF 41/124 reads (33%) | called by mutect2, varscan2
- ZNF708 | c.162C>A p.T54= | Silent (SNP) | VAF 57/170 reads (34%) | called by muse, mutect2, varscan2
- ZNF727 | c.1239A>G p.K413= | Silent (SNP) | VAF 95/284 reads (33%) | catalogued as rs1174149306; called by muse, mutect2, varscan2
- AC116351.1 | n.1115T>A | RNA (SNP) | VAF 19/71 reads (27%) | called by muse, mutect2, varscan2
- AC233702.8 | chr17:21551170 C>A | 5'Flank (SNP) | VAF 14/313 reads (4%) | called by muse, mutect2
- AFF4 | c.2637+38C>G | Intron (SNP) | VAF 7/134 reads (5%) | called by muse, mutect2
- AGMO | c.1263+58994T>A | Intron (SNP) | VAF 74/234 reads (32%) | called by muse, mutect2, varscan2
- AL590617.2 | n.1704C>G | RNA (SNP) | VAF 39/104 reads (38%) | called by muse, mutect2, varscan2
- ANKMY2 | c.1012-1098A>G | Intron (SNP) | VAF 66/178 reads (37%) | called by muse, mutect2, varscan2
- AP001496.2 | n.813C>G | RNA (SNP) | VAF 70/798 reads (9%) | called by muse, mutect2
- ARMCX4 | c.1038+826G>T | Intron (SNP) | VAF 89/116 reads (77%) | called by muse, mutect2, varscan2
- CCDC39 | n.655G>A | RNA (SNP) | VAF 108/365 reads (30%) | called by muse, mutect2, varscan2
- CLIP2 | c.2479+727T>G | Intron (SNP) | VAF 78/257 reads (30%) | called by muse, mutect2, varscan2
- CNGA3 | c.215+286C>G | Intron (SNP) | VAF 88/223 reads (39%) | called by muse, mutect2, varscan2
- CTNNA2 | c.1057-64864G>T | Intron (SNP) | VAF 79/244 reads (32%) | called by muse, varscan2
- CTSC | c.*40G>A | 3'UTR (SNP) | VAF 101/178 reads (57%) | catalogued as rs772060942; called by muse, mutect2, varscan2
- CYP46A1 | c.-28C>A | 5'UTR (SNP) | VAF 57/140 reads (41%) | called by muse, mutect2, varscan2
- DEFB118 | c.-8C>A | 5'UTR (SNP) | VAF 105/250 reads (42%) | catalogued as COSV99489299; called by muse, mutect2, varscan2
- DPP9 | c.2245-311G>T | Intron (SNP) | VAF 50/145 reads (34%) | called by muse, mutect2, varscan2
- EIF3H | c.290-30152A>G | Intron (SNP) | VAF 68/133 reads (51%) | catalogued as rs983189100; called by muse, mutect2, varscan2
- FAM27E5 | n.351G>T | RNA (SNP) | VAF 155/596 reads (26%) | called by muse, mutect2, varscan2
- FBXO16 | c.*133G>A | 3'UTR (SNP) | VAF 126/225 reads (56%) | called by muse, mutect2, varscan2
- GALNT13 | c.1396-1019G>T | Intron (SNP) | VAF 50/177 reads (28%) | called by muse, mutect2, varscan2
- GALNT13 | c.1531-4602del | Intron (DEL) | VAF 78/243 reads (32%) | called by mutect2, pindel, varscan2
- GALNT17 | c.239-35152C>A | Intron (SNP) | VAF 45/151 reads (30%) | called by muse, mutect2, varscan2
- GALNTL6 | c.138+27A>G | Intron (SNP) | VAF 77/130 reads (59%) | called by muse, varscan2
- GOLGA8S | c.348+27G>A | Intron (SNP) | VAF 25/262 reads (10%) | catalogued as rs1261736749; called by muse, mutect2, varscan2
- GP2 | chr16:20327510 G>T | 5'Flank (SNP) | VAF 92/157 reads (59%) | called by muse, mutect2, varscan2
- GREB1 | c.901+118C>T | Intron (SNP) | VAF 121/291 reads (42%) | called by muse, mutect2, varscan2
- HSDL2 | c.-50C>T | 5'UTR (SNP) | VAF 48/336 reads (14%) | catalogued as rs1233547450; called by muse, mutect2, varscan2
- IGKV1D-27 | n.227_228insC | RNA (INS) | VAF 143/530 reads (27%) | called by mutect2, pindel, varscan2
- KCNH8 | c.571-1018G>T | Intron (SNP) | VAF 33/141 reads (23%) | called by muse, mutect2, varscan2
- LINC00602 | n.181G>T | RNA (SNP) | VAF 73/201 reads (36%) | called by muse, mutect2, varscan2
- MAP4 | c.2000-13906C>T | Intron (SNP) | VAF 37/69 reads (54%) | catalogued as rs763846164; called by muse, mutect2, varscan2
- MAVS | c.*805A>T | 3'UTR (SNP) | VAF 175/574 reads (30%) | called by muse, mutect2, varscan2
- MDGA2 | c.2752+1506A>T | Intron (SNP) | VAF 23/84 reads (27%) | called by muse, mutect2, varscan2
- MED9 | c.-10C>A | 5'UTR (SNP) | VAF 132/209 reads (63%) | catalogued as rs767825328, COSV99245724; called by muse, mutect2, varscan2
- MIA2 | chr14:39265326 C>T | 5'Flank (SNP) | VAF 80/250 reads (32%) | catalogued as COSV99697141; called by muse, mutect2, varscan2
- MYLK | c.773+61C>A | Intron (SNP) | VAF 206/290 reads (71%) | called by muse, mutect2, varscan2
- NPIPB1P | n.493G>T | RNA (SNP) | VAF 497/985 reads (50%) | called by muse, mutect2, varscan2
- NPIPB1P | n.204A>G | RNA (SNP) | VAF 160/374 reads (43%) | called by muse, mutect2, varscan2
- OR2M1P | n.594T>A | RNA (SNP) | VAF 102/685 reads (15%) | called by muse, mutect2, varscan2
- OR52Z1 | n.482C>G | RNA (SNP) | VAF 76/216 reads (35%) | called by muse, mutect2, varscan2
- OR5E1P | n.807del | RNA (DEL) | VAF 80/204 reads (39%) | called by mutect2, varscan2
- PHKB | c.2427+976A>G | Intron (SNP) | VAF 217/380 reads (57%) | called by muse, mutect2, varscan2
- PIP5K1B | c.69+1526A>T | Intron (SNP) | VAF 268/518 reads (52%) | called by muse, varscan2
- PKP4 | c.-2G>T | 5'UTR (SNP) | VAF 38/128 reads (30%) | catalogued as COSV101080675; called by muse, mutect2, varscan2
- POM121L4P | n.1023G>T | RNA (SNP) | VAF 336/885 reads (38%) | catalogued as rs973264018; called by muse, varscan2
- POM121L4P | n.1279G>C | RNA (SNP) | VAF 41/872 reads (5%) | called by muse, mutect2
- PPFIA2 | c.2643-12800C>T | Intron (SNP) | VAF 132/188 reads (70%) | called by muse, mutect2, varscan2
- PSG4 | c.*25T>C | 3'UTR (SNP) | VAF 178/319 reads (56%) | catalogued as rs777667689; called by muse, mutect2, varscan2
- PTS | chr11:112226404 G>T | 5'Flank (SNP) | VAF 20/152 reads (13%) | catalogued as rs1440594489; called by muse, mutect2, varscan2
- RIMS2 | c.698+53068T>G | Intron (SNP) | VAF 148/326 reads (45%) | called by muse, mutect2, varscan2
- RNF217-AS1 | n.857G>A | RNA (SNP) | VAF 57/196 reads (29%) | catalogued as rs911773586; called by muse, mutect2, varscan2
- RNU6-714P | chr9:92818353 T>A | 5'Flank (SNP) | VAF 163/294 reads (55%) | called by muse, mutect2, varscan2
- SCN2A | c.4446+20A>G | Intron (SNP) | VAF 11/224 reads (5%) | called by muse, mutect2
- SLC1A3 | c.181+4158C>A | Intron (SNP) | VAF 73/259 reads (28%) | called by muse, mutect2, varscan2
- SNAP91 | c.130+17421G>A | Intron (SNP) | VAF 62/206 reads (30%) | catalogued as rs1323219725; called by muse, mutect2, varscan2
- SNORD116-22 | chr15:25092128 C>A | 3'Flank (SNP) | VAF 101/184 reads (55%) | called by muse, mutect2, varscan2
- SNORD116-22 | chr15:25092129 C>A | 3'Flank (SNP) | VAF 96/173 reads (55%) | called by muse, mutect2, varscan2
- SNTB1 | c.*201G>C | 3'UTR (SNP) | VAF 89/267 reads (33%) | called by muse, mutect2, varscan2
- SPANXB1 | c.*4G>A | 3'UTR (SNP) | VAF 218/704 reads (31%) | called by muse, varscan2
- SSPOP | n.4500G>A | RNA (SNP) | VAF 74/217 reads (34%) | catalogued as rs564553548; called by muse, mutect2, varscan2
- TMEM218 | c.-111+17A>G | Intron (SNP) | VAF 14/119 reads (12%) | catalogued as rs1409605283; called by mutect2, varscan2
- TMEM231 | c.664+18C>A | Intron (SNP) | VAF 103/203 reads (51%) | called by muse, mutect2, varscan2
- TRAV18 | c.-19T>A | 5'UTR (SNP) | VAF 80/202 reads (40%) | called by muse, mutect2, varscan2
- TRIM41 | c.1141-202A>T | Intron (SNP) | VAF 119/188 reads (63%) | called by muse, mutect2, varscan2
- TRIM51BP | n.1039G>A | RNA (SNP) | VAF 39/540 reads (7%) | catalogued as rs779739236; called by muse, mutect2
- TSEN15 | c.354-1533G>T | Intron (SNP) | VAF 28/177 reads (16%) | catalogued as rs192099886; called by muse, mutect2, varscan2
- TTC6 | c.1201-4075A>T | Intron (SNP) | VAF 62/211 reads (29%) | called by muse, mutect2, varscan2
- TTN | c.10360+3193C>T | Intron (SNP) | VAF 208/577 reads (36%) | called by muse, mutect2, varscan2
- USP2 | chr11:119381786 G>A | 5'Flank (SNP) | VAF 26/275 reads (9%) | catalogued as rs764380912; called by muse, mutect2
- WAC | c.1289-430A>T | Intron (SNP) | VAF 94/278 reads (34%) | called by muse, mutect2, varscan2
- WDR91 | chr7:135211531 C>A | 5'Flank (SNP) | VAF 42/359 reads (12%) | catalogued as rs1036980596, COSV100615881; called by muse, mutect2, varscan2
- WT1 | chr11:32438577 C>T | 5'Flank (SNP) | VAF 162/462 reads (35%) | called by muse, mutect2, varscan2
- ZIC4 | c.*38G>T | 3'UTR (SNP) | VAF 77/216 reads (36%) | called by muse, mutect2, varscan2
- ZNF467 | c.*79C>T | 3'UTR (SNP) | VAF 12/170 reads (7%) | called by muse, mutect2
